Somatic mutation profile of tumor specimen 0DFRTL from CCDI case PBBRNE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,828 days).
Specimen 0DFRTL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e74b2e4-eec4-4e6e-9b7f-f67300ef3250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRTP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4dd1131-caea-4834-937a-07b446b33f62

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDE5A | c.2227C>A p.Q743K | Missense Mutation (SNP) | VAF 128/701 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs546809053; called by muse, mutect2, varscan2
- EPHA6 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 34/692 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- SUV39H1 | c.1136T>C p.M379T | Missense Mutation (SNP) | VAF 22/618 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 62/1272 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
